TCGA case TCGA-F9-A4JJ — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6264f0dd-cc82-45f3-bee0-64f52307d324

Demographics
Sex at birth: female; Race: black or african american; Country of residence at enrollment: United States; Age at index: 35 years; Vital status: Dead; Days to death: 325 days.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 35.3 years (12,893 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC clinical T: T3a; AJCC clinical N: NX; AJCC clinical M: MX; AJCC clinical stage: Stage III; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 325 days.
   Pathology details: Consistent pathology review: Yes; Prcc type: Type 2.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 112 days; Days to treatment end: 134 days; Treatment dose: 3,500 cGy; Number of fractions: 14; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 124 days; Days to treatment end: 131 days; Treatment dose: 2,000 cGy; Number of fractions: 5; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 133 days; Days to treatment end: 133 days; Treatment dose: 800 cGy; Number of fractions: 1; Treatment anatomic sites: Distant Site.
2. Metastasis of diagnosis 1 (Papillary adenocarcinoma, NOS). Age at diagnosis: 35.6 years (13,002 days); Days to diagnosis: 109 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 109 days; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 137 days; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 97 days; Disease response: With Tumor.
- Day 109 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 109 days.
- Day 109 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 109 days.
- Days to follow up: 325 days; Disease response: With Tumor.

Molecular and laboratory tests
- Calcium: Normal.
- Leukocytes: Normal.
- Platelets: Elevated.
- Hemoglobin: Low.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 61 kg; Height: 162 cm; BMI: 23.2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-F9-A4JJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,180 mg.
  Slide TCGA-F9-A4JJ-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-F9-A4JJ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-F9-A4JJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: No; Tobacco smoking history indicator: 1.
- Follow-up form: Lost to follow-up: No; New tumor event surgery: Yes; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No; New tumor event surgery met: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 325 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 325 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 109 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-F9-A4JJ-01A-11D-A253-01): tumor purity 0.74, ploidy 1.66, whole-genome doublings 0.
